Surgical pathology report (de-identified scan), TCGA case TCGA-D7-8578, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-8578-01A (Primary Tumor).

Material:

1) Material: stomach, stomach with the tumour. Method of collection: Total organ resection

Histopathological diagnosis:

Examination performed on:

Stomach adenocarcinoma (G2, pT2, pNO).

Macroscopic description:

The specimen consisting of the pyloric part of the stomach body, after being incised along the greater curvature, sized 19 x 14 cm. Ulcerous tumour in the pyloric region on the lesser curvature sized 3.2 x 2.9 x 0.8 cm.

Distance from the proximal end: 1.7 cm, from distal end: 3.6 cm.

Microscopic description:

Gastric adenocarcinoma (intestinal type); the tumour infiltrates into the stomach wall and fat tissue. Incision lines and nodes (3) – free of neoplastic lesions.

Assistant:

Pathologist:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 3da4b9d7-a84b-4aec-92f3-fb8f810adcae (TCGA-D7-8578.886CCD09-D330-4B4A-B8B9-04A590C53947.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).